Somatic mutation profile of tumor specimen 0DQZ4F from CCDI case PBCFRD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.6 years (4,966 days).
Specimen 0DQZ4F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3495f856-6c55-47f8-97af-6f3bf48d78e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQZ3I (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85d8e7b5-6542-407b-b350-4bd82d583438

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Frame Shift Del 1, Nonstop Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM120B | c.1922C>G p.T641S | Missense Mutation (SNP) | VAF 81/302 reads (27%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs1487249900; called by muse, mutect2, varscan2
- GRIA1 | c.2721A>C p.*907Yext*52 | Nonstop Mutation (SNP) | VAF 21/360 reads (6%) | catalogued as COSV53588898; called by muse, mutect2
- TTN | c.62035C>T p.R20679C (on ENST00000591111; = p.R13255C on NM_003319.4) | Missense Mutation (SNP) | VAF 95/352 reads (27%) | PolyPhen possibly damaging (0.648); catalogued as rs772361876, COSV59865594, COSV60239584; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DLGAP3 | c.1397del p.E466Gfs*2 | Frame Shift Del (DEL) | VAF 32/142 reads (23%) | called by mutect2, pindel, varscan2
- PTPRG | c.1672G>T p.A558S | Missense Mutation (SNP) | VAF 19/376 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.112); called by muse, mutect2
- RLBP1 | c.459G>C p.K153N | Missense Mutation (SNP) | VAF 18/464 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.438); called by muse, mutect2
- SMARCB1 | c.900G>A p.A300= (on ENST00000263121; = p.A346= on NM_003073.5) | Silent (SNP) | VAF 38/227 reads (17%) | catalogued as rs777241431, COSV99320266; ClinVar: likely benign; called by muse, mutect2, varscan2
